Gene-level copy-number profile of tumor specimen TCGA-DD-AACY-01A from TCGA case TCGA-DD-AACY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 61.1 years (22,332 days).
Specimen TCGA-DD-AACY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.a263c81e-4782-4414-a05f-ebf7b848f745.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/afaa646c-da07-4a23-be13-5417ad11b9eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,718; copy number 2: 44,789; copy number 3: 4,756; copy number 4: 2,820; copy number 5: 374; copy number 6: 268; copy number 7: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACY-01A-11D-A40Q-01): tumor purity 0.85, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 731 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,175,850–159,147,096, 40 genes, copy number 5: ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P, PYHIN1, IFI16, AIM2, RAD1P2.
- chr8:92,351,912–142,091,619, 691 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,904. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
